Gene-level copy-number profile of tumor specimen MP2PRT-PATHCV-TMP1-A from MP2PRT case MP2PRT-PATHCV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,593 days).
Specimen MP2PRT-PATHCV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3cf7a3f6-e6fa-4101-b13b-c24cda0630d3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATHCV-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/78f9e0b7-26ad-462d-919c-eb96a049a70b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 240; copy number 1: 3,073; copy number 2: 55,574; copy number 3: 7.

Homozygous deletions (total copy number 0; autosomes only): 240 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,234,912, 38 genes (within-gene range 0–2): MALLP2, MIR4436A, IGKC, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29.
- chr2:89,989,987–89,990,221, 1 gene: IGKV3D-25.
- chr14:22,449,113–22,459,156, 5 genes (within-gene range 0–2): TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3.
- chr14:22,483,004–22,505,167, 18 genes (within-gene range 0–2): TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36.
- chr14:105,672,308–106,672,073, 160 genes (within-gene range 0–2) (broad region; genes not listed).
- chr22:22,032,745–22,162,681, 18 genes (within-gene range 0–2): IGLVI-68, AC245452.4, AC245452.3, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 217. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
